Somatic mutation profile of tumor specimen TARGET-20-PAPWIU-09A (aliquot TARGET-20-PAPWIU-09A-02D) from TARGET case TARGET-20-PAPWIU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.1 years (4,421 days).
Specimen TARGET-20-PAPWIU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a16c332-17da-4098-8c9f-82fbbaa3091d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAPWIU-14A (Bone Marrow Normal), aliquot TARGET-20-PAPWIU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9122306e-5acc-4211-afe4-d69c328cf217

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/180 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs28941778, CM003970, CM127190, CM910413, COSV60066459, COSV60067963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CBFA2T2 | c.952C>G p.R318G | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); called by muse, mutect2
- CEBPA | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
